Somatic mutation profile of tumor specimen TCGA-EL-A3ZQ-01A (aliquot TCGA-EL-A3ZQ-01A-11D-A23M-08) from TCGA case TCGA-EL-A3ZQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 78.8 years (28,783 days).
Specimen TCGA-EL-A3ZQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59342de7-0e28-488e-833e-809aa9f08b85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZQ-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZQ-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5985ad52-03cd-47e6-a81b-c33f85e9ac46

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACSS3 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs368706037; called by mutect2, varscan2
- DIP2C | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55170279; called by muse, mutect2, varscan2
- DNAJC12 | c.503-2A>G p.X168_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99830610; called by muse, mutect2, varscan2
- FOLH1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs778134535, COSV57046475, COSV57049371; called by muse, mutect2, varscan2
- SMCR8 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767917908, COSV58179645; called by muse, mutect2, varscan2
- UGGT2 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV65025745; called by muse, mutect2, varscan2
- TG | c.1038dup p.H347Afs*14 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- NTNG1 | c.435A>C p.T145= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV53981217; called by muse, mutect2, varscan2
